Somatic mutation profile of tumor specimen TARGET-20-PASFZN-04A (aliquot TARGET-20-PASFZN-04A-01D) from TARGET case TARGET-20-PASFZN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.3 years (6,334 days).
Specimen TARGET-20-PASFZN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2a072c4-70b7-43a5-9b51-9150b1d61c70.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFZN-14A (Bone Marrow Normal), aliquot TARGET-20-PASFZN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79334fc1-cc92-441f-afd1-46addb63cfa4

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 4, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1102_1103dup p.S369Gfs*69 | Frame Shift Ins (INS) | VAF 64/199 reads (32%) | catalogued as rs1564972935, COSV60075684, COSV60080453; called by mutect2, pindel, varscan2
- CACNA1A | c.6854C>T p.P2285L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ETV6 | c.257_258insT p.F87Vfs*2 | Frame Shift Ins (INS) | VAF 62/173 reads (36%) | called by mutect2, pindel, varscan2
- SRCAP | c.6739_6740insCC p.R2247Pfs*61 | Frame Shift Ins (INS) | VAF 33/83 reads (40%) | called by mutect2, varscan2
- SRCAP | c.6740delinsCCC p.R2247Pfs*61 | Frame Shift Ins (INS) | VAF 12/73 reads (16%) | called by mutect2*, pindel, varscan2*
- LAMB2 | c.5261-25dup | Intron (INS) | VAF 32/94 reads (34%) | catalogued as rs746603871; called by mutect2, varscan2
